Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A3HZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A3HZ-01A (Primary Tumor).

[page 1 of 3]
Collection Date:
Hospital of Origin:
Copy to:

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Lymph nodes, left pelvic, dissection:
Negative for neoplasm, four nodes examined (0/4).
B. Lymph nodes, right pelvic, dissection:
Negative for neoplasm, five nodes examined (0/5).
C. Uterus, bilateral ovaries and fallopian tubes, radical
hysterectomy and bilateral salpingo-oophorectomy:
Cervix, invasive squamous cell carcinoma.
Grade III.
Tumor located in endocervix with extension into lower
uterine segment, endometrial cavity and myometrium of
uterine corpus.
Tumor size: 7 x 5 cm.
Tumor invades completely through myometrium to involve
serosa (25 mm depth).
Lymphovascular space invasion present.
Surgical margins free of tumor (cervical and parametrial: no
tumor involves serosa of the uterine corpus).
Endometrium, completely replaced by squamous carcinoma.
Myometrium, no additional diagnoses.
Right ovary, benign simple cyst.
Left ovary, benign simple cyst.
Bilateral fallopian tubes, no pathologic change.
D. Uterine artery, biopsy:
No pathologic change.
Staging (AJCC 2010): pT2a2,N0 (FIGO: IIA2)

COMMENTS:

The tumor is a poorly differentiated invasive large cell
non-keratinizing squamous cell carcinoma. The tumor has an
unusual distribution of completely replacing the endometrium
with diffuse invasion through the myometrium to involve the
serosa of the uterine corpus. Sections including the cervix
show an unremarkable transformation zone, but squamous cell
carcinoma is present in the proximal portion of the
endocervix and lower uterine segment region. The
possibility of the squamous cell carcinoma arising in the
endometrium was considered since the tumor appears to be
centered in the uterine corpus and squamous cell carcinomas

1CB-0-3

carcinoma, squamous cell, large cell non-keratinizing 8072/3

Site: cervix, NOS C53.9

12/2/11

[page 2 of 3]
primary of the endometrium c r on vary rare occasions. However, endocervical origin is favored since there is tumor present in the upper portion of the endocervix. It is felt to be more likely that the tumor originated in the endocervix, which is much more common than endometrium, with subsequent extension into the uterine corpus. The diagnosis of primary squamous cell carcinoma of the endometrium is generally made only when the cervix and endocervix are free of neoplasm.

CLINICAL HISTORY:

Preoperative Diagnosis: Endometrial cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left pelvic lymph nodes
- B. Right pelvic lymph nodes
- C. Uterus, cervix, BSO
- D. Ureter and artery

CODES:

88307

88307

88309

88304

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

GROSS DESCRIPTION:

- A. The first container A is labeled #1. The specimen consists of a portion of fibroadipose tissue measuring 5.5 x 5.0 x 1.5 cm. Sectioning reveals five probable lymph nodes measuring from 0.7 to 1.5 cm. Representative sections from the lymph nodes were examined at the time of surgery. The lymph nodes are entirely submitted in cassettes as follows: frozen section--1; lymph node remnants--2.
- B. The second container B is labeled #2. The specimen consists of a portion of fibroadipose tissue measuring 6.5 x 4.0 x 1.5 cm. Sectioning reveals five probable lymph nodes measuring from 1.0 to 2.5 cm. Sections from the lymph nodes were examined at the time of surgery. The lymph nodes are subsequently entirely submitted in cassettes as follows: frozen section FS1--1; frozen section FS2--2; lymph node remnants--3.
- C. The third container C is labeled uterus, cervix, BSO. The specimen consists of a previously bisected uterus with attached cervix, attached right adnexa and separately submitted left adnexa. The uterus measures 8.0 x 7.5 x 5.0 cm and weighs 191 grams. The serosal surface of the uterus is gray tan to brown tan. The serosa has been inked. Sections from the parametrium have been taken. The cervix measures 4.0 cm in length and 3.0 cm in diameter.

[page 3 of 3]
The ectocervix is gray to brown with hemorrhage. There is bilateral paracervical tissue attached to the specimen. The uterus is bisected. The endocervical canal is light tan to brown tan. On sectioning through the wall the cut surface is yellow gray fibrous. Within the upper portion of the endocervical canal there is a yellow gray nodular mass, which appears to be an extension of the endometrial mass noted. The endometrial cavity is obliterated by a yellow gray mass measuring 7.0 x 5.0 cm, which extends through the lower uterine segment and as previously mentioned describes portions of the upper endocervical canal. On sectioning the mass shows full thickness invasion and abuts the inked serosal surface. The lesion involves almost the entire myometrium and there is focal areas of rim of normal gray tan trabecular myometrium identified. The attached right ovary measures 2.0 x 1.0 x 0.5 cm. The surface is yellow gray. On sectioning the cut surface is yellow tan. There are no lesions identified. The right fallopian tube measures 6.0 cm in length and up to 0.4 cm in diameter. There are two metal clips noted within the proximal portion. The surface is gray to brown tan. On sectioning there is no material or lesions identified within the lumen. The separately submitted left ovary measures 4.0 x 2.0 x 1.5 cm. The surface is yellow to gray tan. On sectioning there reveals a serous cyst measuring up to 2.0 cm containing clear serous fluid. There are no excrescences noted. The left fallopian tube measures 3.0 cm in length and 0.3 cm in diameter. The surface is gray to brown tan. On sectioning there are no material or lesions identified within the lumen. The fallopian tube appears grossly unremarkable. Received with the specimen are two cassettes, one green and one yellow, labeled. Representative sections are submitted in cassettes as follows: cervix from 12:00 to 3:00--1; 3:00 to 6:00--2; 6:00 to 9:00--3; 9:00 to 12:00--4; full thickness sections from the lesion--5 to 9; lower uterine segment--10; left paracervical tissue--11; right paracervical tissue--12; left parametrial tissue--13; right parametrial tissue--14; right ovary--15; right fallopian tube--16; left ovary--17; left fallopian tube--18. D. The fourth container D is labeled, left ureter and artery. The specimen consists of a piece of yellow brown fibroadipose tissue measuring 1.5 x 1.0 x 0.2 cm. The specimen is entirely submitted in a single cassette

INTRA-PROCEDURE CONSULTATION:

FSA: 'Left pelvic lymph nodes: Negative for neoplasm (four nodes)'.

FSB: 'Right pelvic nodes: Negative for neoplasm (five nodes)'

Source: NCI Genomic Data Commons file a1ea57c2-3070-4522-9790-092f381af178 (TCGA-FU-A3HZ.5A91D73E-6F08-4439-AA0D-E73186C81DCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).